Gene-level copy-number profile of tumor specimen ALCH-B1XO-TTP1-A from ALCHEMIST case ALCH-B1XO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.6 years (22,130 days).
Specimen ALCH-B1XO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d13a1c3b-5038-4c95-971f-2a0c46617542.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/5363602b-f9bd-440b-ae79-ae8939ba7d39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 6,899; copy number 2: 50,609; copy number 3: 1,251; copy number 4: 24; copy number 5: 15; copy number 6: 5; copy number 7: 1; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,481,362–28,481,480, 1 gene (within-gene range 0–2): RNU6ATAC27P.
- chr1:28,505,980–28,510,892, 3 genes (within-gene range 0–2): SNHG3, SNORA73A, SNORA73B.
- chr1:112,849,821–112,877,871, 1 gene (within-gene range 0–1): LINC01357.
- chr2:89,906,757–89,907,246, 1 gene: IGKV3D-34.
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr5:139,644,460–139,683,882, 3 genes: AC113361.1, CXXC5, CXXC5-AS1.
- chr5:139,740,951–139,747,406, 1 gene (within-gene range 0–1): PSD2-AS1.
- chr5:149,358,037–149,369,653, 1 gene: PCYOX1L.
- chr6:110,848,546–110,864,451, 4 genes (within-gene range 0–1): SNORA40C, RNU6-1115P, CNN2P9, Z84480.1.
- chr7:99,472,890–99,504,857, 2 genes (within-gene range 0–2): ZNF789, ZNF394.
- chr9:121,519,816–121,520,424, 1 gene: HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr10:68,503,152–68,503,259, 1 gene (within-gene range 0–1): Y_RNA.
- chr12:121,777,754–121,803,403, 1 gene (within-gene range 0–2): RHOF.
- chr12:122,007,434–122,020,063, 1 gene (within-gene range 0–1): AC069503.1.
- chr14:73,567,620–73,575,658, 2 genes: ACOT2, NT5CP1.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:93,934,166–93,976,739, 3 genes (within-gene range 0–2): ASB2, AL132642.1, MIR4506.
- chr15:21,328,380–21,951,323, 36 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr17:2,748,078–2,748,182, 2 genes (within-gene range 0–1): MIR1253, hsa-mir-1253.
- chr17:44,290,856–44,315,315, 4 genes (within-gene range 0–1): RN7SL507P, RUNDC3A-AS1, U3, RNU6-453P.
- chr17:44,328,613–44,353,106, 2 genes: AC003043.1, GRN.
- chr19:12,643,275–12,696,631, 13 genes: RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS, AC010422.2, GNG14, FBXW9, AC018761.4.
- chr19:12,751,702–12,758,458, 1 gene: BEST2.
- chr21:42,831,040–42,836,477, 1 gene: AP001628.1.
- chr22:17,121,560–17,132,104, 1 gene: LINC01664.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,712,572–136,724,742, 1 gene, copy number 5 (within-gene range 4–5): DIPK1B.
- chr9:136,738,167–136,758,543, 2 genes, copy number 5: LCN10, LCN8.
- chr9:136,844,415–136,860,799, 3 genes, copy number 5 (within-gene range 3–7): AJM1, PHPT1, MAMDC4.
- chr9:136,992,422–137,054,061, 9 genes, copy number 5–7: PAXX, CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1, ENTPD2, AL807752.4.
- chr9:137,077,517–137,086,817, 2 genes, copy number 5–9: UAP1L1, MAN1B1-DT.
- chr16:28,700,294–28,701,540, 1 gene, copy number 6: CDC37P1.
- chr17:18,476,737–18,551,705, 5 genes, copy number 6–10 (within-gene range 3–10): LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Autosomal genes at a single copy (total copy number 1): 4,043. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
